Gene-level copy-number profile of tumor specimen TCGA-YL-A8HO-01A from TCGA case TCGA-YL-A8HO, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 67.1 years (24,509 days).
Specimen TCGA-YL-A8HO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.625fe7dd-a0fe-48cf-aabd-54560205a122.absolute_liftover.gene_level_copy_number.v36.tsv, workflow ABSOLUTE segment calls lifted over to GRCh38 (Affymetrix SNP 6.0); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 3,602 have no estimate.
https://portal.gdc.cancer.gov/files/9fc98485-7837-4b71-ac4b-449cbd5c63bb

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 479; copy number 1: 9,627; copy number 2: 40,670; copy number 3: 3,258; copy number 4: 2,987.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-YL-A8HO-01A-11D-A363-01): tumor purity 0.55, ploidy 2.05, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 479 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:132,468,147–132,490,777, 3 genes: Y_RNA, AC116366.1, IRF1.
- chr5:167,937,717–167,953,469, 1 gene: AC008464.1.
- chr10:52,450,874–53,766,614, 9 genes (within-gene range 0–1): LNCAROD, MBL2, Y_RNA, AC073174.1, LINC02672, SNRPEP8, AC036101.1, RNA5SP318, AL365496.1.
- chr10:55,247,755–56,596,031, 9 genes (within-gene range 0–1): AC016822.1, AL355314.1, AL355314.2, MTRNR2L5, GAPDHP21, AC069545.1, ZWINT, AC010996.1, AC025039.1.
- chr13:31,846,713–32,299,125, 1 gene (within-gene range 0–1): FRY.
- chr13:31,975,167–37,139,585, 72 genes (broad region; genes not listed).
- chr13:38,965,925–55,174,548, 316 genes (broad region; genes not listed).
- chr16:35,021,749–35,522,465, 46 genes: AC135776.1, AC135776.2, AC135776.3, CCNYL3, CLUHP11, NAMPTP3, VPS35P1, VN1R68P, VN1R69P, AC023824.5, AC023824.6, UBE2MP1, SLC25A1P4, AC023824.1, AC023824.2, AC023824.4, AC023824.3, TP53TG3GP, RARRES2P5, FGFR3P5, FRG2JP, RARRES2P6, AGGF1P8, FRG2HP, RARRES2P9, AGGF1P9, C2orf69P4, LINC01566, FRG2GP, AGGF1P4, FRG2IP, RARRES2P7, AGGF1P5, C2orf69P3, AC018558.4, ZNF971P, AC018558.6, FRG2DP, RARRES2P10, AGGF1P6, AC018558.2, C2orf69P2, AC018558.3, AC018558.7, AC018558.1, TP53TG3HP.
- chr16:64,242,608–64,600,247, 3 genes: AC012322.1, AC093536.1, AC092131.1.
- chr16:65,141,751–65,646,947, 6 genes: LINC02126, AC009055.2, AC009055.1, LINC00922, AC092138.2, AC092138.1.
- chr19:42,752,686–42,855,691, 1 gene (within-gene range 0–2): PSG8.
- chr19:42,821,863–43,171,515, 11 genes (within-gene range 0–2): PSG8-AS1, PSG10P, PSG1, PSG6, PSG7, CEACAMP7, AC004784.1, PSG11, CEACAMP8, PSG2, CEACAMP9.
- chr20:16,684,108–16,684,404, 1 gene: AL135938.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 9,627. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
